Somatic mutation profile of tumor specimen TCGA-FE-A22Z-01A (aliquot TCGA-FE-A22Z-01A-11D-A17V-08) from TCGA case TCGA-FE-A22Z, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 61.0 years (22,286 days).
Specimen TCGA-FE-A22Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18b2da8a-27eb-4de4-801e-cf2e0e502e17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A22Z-10A (Blood Derived Normal), aliquot TCGA-FE-A22Z-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cc0b98e-b582-4e05-8d50-d23873cc5a78

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Splice Region 2, 5'Flank 2, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL19A1 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.139); catalogued as COSV59587674; called by muse, mutect2, varscan2
- COL5A1 | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV65674543; called by muse, mutect2
- CPLANE1 | c.7813-4A>G | Splice Region (SNP) | VAF 6/20 reads (30%) | catalogued as COSV57073888; called by muse, mutect2, varscan2
- HLA-DMB | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66870954; called by muse, mutect2, varscan2
- JAKMIP3 | c.138C>T p.V46= | Splice Region (SNP) | VAF 10/44 reads (23%) | catalogued as COSV53829156; called by muse, mutect2, varscan2
- MAGEB6 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV66872417, COSV66872579; called by muse, mutect2, varscan2
- MIB1 | c.1123A>T p.I375F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV55094847; called by muse, mutect2, varscan2
- PPEF1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV62996723; called by muse, mutect2, varscan2
- PROSER1 | c.1825A>G p.T609A | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV61489633; called by muse, mutect2, varscan2
- RAI1 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 19/30 reads (63%) | catalogued as COSV55397485; called by muse, mutect2, varscan2
- RHOQ | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53191056; called by muse, mutect2, varscan2
- SH3PXD2A | c.1364C>T p.T455I (on ENST00000369774 / NM_001365079.1; = p.T427I on NM_014631.2) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV60120587; called by muse, mutect2, varscan2
- SORCS3 | c.2383C>T p.R795W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs774027756, COSV63798536; called by muse, mutect2, varscan2
- USP9X | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV61075025; called by muse, mutect2, varscan2
- CENPI | c.1161G>A p.R387= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV54506249; called by muse, mutect2, varscan2
- CTSW | c.1050T>C p.N350= | Silent (SNP) | VAF 51/142 reads (36%) | catalogued as rs748440000, COSV57173178; called by muse, mutect2, varscan2
- F8 | c.4917C>T p.P1639= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as rs147629393, COSV64278586; called by muse, mutect2, varscan2
- HDAC5 | c.675C>T p.S225= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV56821870; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65501054 A>C | 5'Flank (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- TAF8 | chr6:42048547 G>C | 5'Flank (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100881171; called by muse, mutect2, varscan2
- ZNF207 | c.-86C>A | 5'UTR (SNP) | VAF 47/130 reads (36%) | catalogued as COSV100340635; called by muse, mutect2, varscan2
